Somatic mutation profile of tumor specimen TCGA-G3-A3CK-01A (aliquot TCGA-G3-A3CK-01A-11D-A20W-10) from TCGA case TCGA-G3-A3CK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.5 years (22,462 days).
Specimen TCGA-G3-A3CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f35c9754-a995-4c54-88f7-46b47a6e7cc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A3CK-10A (Blood Derived Normal), aliquot TCGA-G3-A3CK-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f684097-e498-4676-a706-3992f567b675

The open-access MAF lists 258 somatic variants for this specimen: 195 protein-altering or splice-affecting, 49 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 49, Frame Shift Del 9, Nonsense Mutation 8, Splice Site 7, Splice Region 7, Intron 6, In Frame Del 5, 5'UTR 4, 3'UTR 2, Translation Start Site 2, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.1450A>G p.T484A | Missense Mutation (SNP) | VAF 59/154 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV67262337; called by muse, mutect2, varscan2
- PACS2 | c.261A>C p.Q87H | Missense Mutation (SNP) | VAF 63/183 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV57651615, COSV57655980; called by muse, mutect2, varscan2
- ABCB1 | c.2888T>G p.L963W | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55949208; called by muse, mutect2
- AC005324.2 | c.560T>G p.L187R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100372047; called by mutect2, varscan2
- ADCY2 | c.2276A>G p.Y759C | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs1191187300, COSV57868439; called by muse, mutect2, varscan2
- ADGRL1 | c.4250C>A p.P1417H (on ENST00000340736 / NM_001008701.3; = p.P1412H on NM_014921.5) | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.304); catalogued as COSV61564359; called by muse, mutect2, varscan2
- ADGRV1 | c.13502T>C p.L4501P | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV67983372; called by muse, varscan2
- ADGRV1 | c.13507A>C p.S4503R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs764716759, COSV67979835, COSV67980159, COSV67983377; called by muse, varscan2
- AFF3 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.358); catalogued as COSV57850910; called by muse, mutect2, varscan2
- ALOX5 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs778612367, COSV65552020; called by muse, mutect2, varscan2
- ANGPTL3 | c.1247A>C p.K416T | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs775345711, COSV52002512; called by muse, mutect2, varscan2
- ARFGEF1 | c.4343C>T p.A1448V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV51606705; called by muse, mutect2, varscan2
- ARPP21 | c.1220A>C p.K407T | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV51795687; called by muse, mutect2, varscan2
- AXIN2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 49/184 reads (27%) | catalogued as rs1157452251, COSV61057014; called by muse, mutect2, varscan2
- B4GALT3 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV60527020; called by muse, mutect2, varscan2
- BCL6 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866452181, COSV51651275; called by muse, mutect2, varscan2
- BIRC6 | c.2957A>C p.K986T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV70198155; called by muse, mutect2, varscan2
- BUD23 | c.459C>A p.L153= | Splice Region (SNP) | VAF 109/304 reads (36%) | catalogued as COSV56094808; called by muse, mutect2, varscan2
- C11orf42 | c.160A>C p.K54Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV56410863; called by muse, mutect2, varscan2
- CAPZA2 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV63266368; called by muse, mutect2, varscan2
- CCDC105 | c.218T>A p.F73Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV52963734; called by muse, mutect2, varscan2
- CCDC137 | c.660G>A p.Q220= | Splice Region (SNP) | VAF 72/132 reads (55%) | catalogued as rs373550389; called by muse, mutect2, varscan2
- CD300LB | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV58725559; called by muse, mutect2, varscan2
- CDC20B | c.237A>C p.Q79H | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV57051504, COSV57054667; called by muse, mutect2, varscan2
- CDH9 | c.2317C>A p.R773S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV50256740, COSV50269687; called by muse, mutect2, varscan2
- CHPF | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV60534431; called by muse, mutect2, varscan2
- CIB1 | c.566T>G p.I189S | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153190, COSV60173166; called by muse, mutect2, varscan2
- CLCN6 | c.1973A>T p.K658M | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV56739398; called by muse, mutect2, varscan2
- CMTM8 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV56776726; called by muse, mutect2, varscan2
- CNPY2 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56264250; called by muse, mutect2, varscan2
- CNTN2 | c.2152A>G p.S718G | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59349565; called by muse, mutect2, varscan2
- CNTRL | c.5057T>C p.V1686A | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.039); catalogued as COSV53045989; called by muse, mutect2, varscan2
- COBLL1 | c.3575T>G p.L1192R (on ENST00000392717; = p.L1154R on NM_014900.5) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1177928991, COSV52066529; called by muse, mutect2, varscan2
- CUL9 | c.5204A>G p.Y1735C | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.362); catalogued as COSV52727691; called by muse, mutect2, varscan2
- DDIT3 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV56253987; called by muse, mutect2
- DHX15 | c.2357A>C p.K786T | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV61026018; called by muse, mutect2, varscan2
- DLGAP4 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59416895; called by muse, mutect2, varscan2
- DLX5 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV56032182, COSV99756271; called by muse, mutect2, varscan2
- DMBX1 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs150745846; called by muse, mutect2, varscan2
- DMTN | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV56112306; called by muse, mutect2, varscan2
- DNAH2 | c.10409T>C p.I3470T | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs1469376078, COSV66718601; called by muse, mutect2, varscan2
- EEPD1 | c.1334T>C p.I445T | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV54197314; called by muse, mutect2, varscan2
- EIF4G1 | c.1820A>G p.E607G (on ENST00000346169 / NM_198241.3; = p.E411G on NM_004953.5) | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV59990390; called by muse, mutect2, varscan2
- ELP3 | c.1112T>C p.M371T | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV56458733; called by muse, mutect2
- ENOSF1 | c.953T>G p.F318C (on ENST00000340116 / NM_001354066.2; = p.F270C on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51891978; called by muse, mutect2, varscan2
- FASN | c.7349C>T p.T2450M | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs776351410, COSV60753297; ClinVar: uncertain significance; called by muse, mutect2
- FASN | c.6141A>C p.K2047N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV60753306; called by muse, mutect2, varscan2
- FBN3 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54458521; called by muse, mutect2
- FCF1 | c.363A>C p.L121= | Splice Region (SNP) | VAF 45/126 reads (36%) | catalogued as COSV62044074; called by muse, mutect2, varscan2
- FCHO2 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59272230; called by muse, mutect2, varscan2
- FLNB | c.6780C>G p.Y2260* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV55876894, COSV99914199; called by muse, mutect2, varscan2
- FSCB | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV61217625; called by muse, mutect2, varscan2
- GAD1 | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV64025493; called by muse, mutect2, varscan2
- GALNT1 | c.856G>C p.V286L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV52451882, COSV99322165; called by muse, mutect2, varscan2
- GJB5 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58355969; called by muse, mutect2, varscan2
- GPR25 | c.1084T>G p.*362Eext*? | Nonstop Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV58497982; called by muse, mutect2, varscan2
- GRK3 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.121); catalogued as COSV60793521, COSV60795200; called by muse, mutect2, varscan2
- GTF3C3 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1454104763, COSV55831818; called by muse, mutect2, varscan2
- GUSB | c.1886T>A p.I629N | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59221512; called by muse, mutect2, varscan2
- HERC1 | c.10430C>T p.A3477V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV71247286; called by muse, mutect2, varscan2
- HERC1 | c.7193A>T p.Y2398F | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV71247292; called by muse, mutect2, varscan2
- HERC2 | c.4002C>T p.A1334= | Splice Region (SNP) | VAF 100/280 reads (36%) | catalogued as COSV55319148; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.130T>G p.W44G (on ENST00000354667 / NM_031243.3; = p.W32G on NM_002137.4) | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV61158732; called by muse, mutect2, varscan2
- HSPB2 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV57051627; called by muse, mutect2, varscan2
- ICE1 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56822730; called by muse, mutect2, varscan2
- IGFBP3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV51872259; called by muse, mutect2, varscan2
- IGSF5 | c.956+1G>A p.X319_splice | Splice Site (SNP) | VAF 10/193 reads (5%) | catalogued as COSV66029970; called by muse, mutect2
- IL6ST | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61139708; called by muse, mutect2, varscan2
- INTS8 | c.2987A>C p.*996Sext*6 | Nonstop Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as COSV57375793; called by muse, mutect2, varscan2
- ITPR1 | c.5389T>C p.C1797R (on ENST00000354582; = p.C1742R on NM_002222.7) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1377176027, COSV56977768; called by muse, mutect2, varscan2
- JARID2 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.104); catalogued as COSV59188168; called by muse, mutect2, varscan2
- KATNIP | c.4571T>G p.L1524R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55178641; called by muse, mutect2, varscan2
- KCNJ15 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV60810659; called by muse, mutect2, varscan2
- KEAP1 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263313, COSV50274600, COSV99407315; called by muse, mutect2, varscan2
- KIAA0586 | c.50A>G p.H17R (on ENST00000619416 / NM_001244190.2; = p.H32R on NM_014749.5) | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1467531891, COSV53621460; called by muse, mutect2, varscan2
- KIAA1755 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54075650; called by muse, mutect2, varscan2
- KPNA1 | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60268545; called by muse, mutect2, varscan2
- KPNA1 | c.230T>A p.M77K | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV60268555; called by mutect2, varscan2
- KRT40 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV66696266; called by muse, mutect2, varscan2
- KRT79 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs140167313, COSV57939250; called by muse, mutect2, varscan2
- L1TD1 | c.1928T>C p.L643S | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as rs1240300838, COSV63133411; called by muse, mutect2, varscan2
- LACTB2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV52567612; called by muse, mutect2, varscan2
- LAMA3 | c.3184A>G p.N1062D | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.072); catalogued as COSV58066965; called by muse, mutect2, varscan2
- LEF1 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1413007448, COSV54466244; called by muse, mutect2, varscan2
- LIAS | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV54695512; called by muse, mutect2, varscan2
- LITAF | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59655514; called by muse, mutect2, varscan2
- LRP1 | c.12022G>A p.V4008M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54508339; called by muse, mutect2, varscan2
- LRRC27 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV59808406; called by muse, mutect2, varscan2
- MAGI2 | c.950A>C p.E317A | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV62647561; called by muse, varscan2
- MANF | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV56515801; called by muse, mutect2, varscan2
- MBIP | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV59253833; called by muse, mutect2, varscan2
- MCMBP | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780333288; called by muse, mutect2, varscan2
- MEOX2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56289204; called by muse, mutect2, varscan2
- MON2 | c.1891T>C p.S631P | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.221); catalogued as COSV54805975; called by muse, mutect2, varscan2
- MTREX | c.275T>A p.L92* | Nonsense Mutation (SNP) | VAF 48/106 reads (45%) | catalogued as COSV57925309; called by muse, mutect2, varscan2
- MYOCD | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs763274360, COSV58499858, COSV58502009; called by muse, mutect2, varscan2
- N4BP1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as COSV52210445; called by muse, mutect2, varscan2
- NOP2 | c.499C>T p.R167W (on ENST00000322166 / NM_001258308.2; = p.R163W on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs555886597, COSV59110205; called by muse, mutect2, varscan2
- NOP56 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.261); catalogued as rs759607127, COSV61389638; called by muse, mutect2, varscan2
- NPC1L1 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV56924264; called by muse, mutect2, varscan2
- NRDC | c.1340T>C p.M447T | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61403680; called by muse, mutect2, varscan2
- OR4Q3 | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59178254; called by muse, mutect2, varscan2
- PDE1C | c.2018C>A p.A673E | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.497); catalogued as COSV58510905, COSV58522061; called by muse, mutect2, varscan2
- PDHX | c.1113A>C p.K371N | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV57165546; called by muse, mutect2, varscan2
- PDK2 | c.259T>C p.W87R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV50303492; called by muse, mutect2, varscan2
- PECAM1 | c.2170G>A p.V724M | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs541440037, COSV63811763; called by muse, mutect2, varscan2
- PHLDA1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56997104; called by muse, mutect2, varscan2
- PI4KB | c.979G>T p.E327* (on ENST00000368873 / NM_001369623.1; = p.E339* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 96/207 reads (46%) | catalogued as COSV55016745; called by muse, mutect2, varscan2
- PKD1 | c.12217A>G p.T4073A (on ENST00000262304 / NM_001009944.3; = p.T4072A on NM_000296.4) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV51914280; called by muse, mutect2, varscan2
- PLCD1 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1000883362, COSV58160412; called by muse, mutect2, varscan2
- POU2F2 | c.926G>A p.R309H (on ENST00000526816 / NM_001207025.3; = p.R293H on NM_002698.5) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60761689; called by muse, mutect2, varscan2
- PRKCZ | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66066922; called by muse, mutect2, varscan2
- PRKDC | c.808+1G>T p.X270_splice | Splice Site (SNP) | VAF 35/121 reads (29%) | catalogued as COSV58049652; called by muse, mutect2, varscan2
- PSMA4 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50384597; called by muse, mutect2, varscan2
- RAB40C | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV50193310; called by muse, mutect2, varscan2
- RAB4A | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV64207426; called by muse, mutect2, varscan2
- RAD9A | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV57236224; called by muse, mutect2, varscan2
- RANBP17 | c.1235T>G p.F412C | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV66649079; called by muse, mutect2, varscan2
- RASAL2 | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); catalogued as rs765638263, COSV62712659; called by muse, mutect2, varscan2
- RCC1 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100868067, COSV65779291; called by muse, mutect2, varscan2
- RIN3 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs554426241; called by muse, mutect2, varscan2
- RNF146 | c.500A>C p.K167T (on ENST00000368314 / NM_001242850.2; = p.K166T on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58932234; called by muse, mutect2, varscan2
- RPRD2 | c.1417A>G p.S473G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV64819549; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV58242083; called by muse, mutect2, varscan2
- RXFP2 | c.1940A>C p.D647A | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53634730; called by muse, mutect2, varscan2
- SAMD3 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV60775323; called by muse, mutect2, varscan2
- SART3 | c.1010T>G p.F337C (on ENST00000228284; = p.F319C on NM_014706.4) | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57206764; called by muse, mutect2, varscan2
- SCYL1 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as COSV54212033; called by muse, mutect2, varscan2
- SEPTIN6 | c.18A>G p.I6M | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV59713493; called by muse, mutect2, varscan2
- SH2B3 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57982667; called by muse, mutect2, varscan2
- SLC22A25 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.598); catalogued as COSV100123488, COSV60595498; called by muse, mutect2, varscan2
- SLC2A2 | c.898T>C p.Y300H | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as rs769325995, COSV58585630; called by muse, mutect2, varscan2
- SLC35B1 | c.737A>C p.N246T (on ENST00000649906; = p.N209T on NM_005827.4) | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53602785; called by muse, mutect2, varscan2
- SLC9C1 | c.1660A>T p.K554* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | catalogued as COSV59887496; called by muse, mutect2, varscan2
- SND1 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV61239278; called by muse, mutect2
- SON | c.7034-7T>G | Splice Region (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99279540; called by muse, mutect2, varscan2
- SP3 | c.592A>C p.N198H | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV59467145; called by muse, mutect2, varscan2
- SPATA1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99759909; called by muse, varscan2
- SPTLC2 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53639414; called by muse, mutect2, varscan2
- SRBD1 | c.733A>C p.I245L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV55397849; called by muse, mutect2, varscan2
- SSBP2 | c.571-7A>T | Splice Region (SNP) | VAF 67/183 reads (37%) | catalogued as COSV57796126; called by muse, mutect2, varscan2
- TAF6L | c.1325G>C p.R442P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV53668104; called by muse, mutect2, varscan2
- TAP1 | c.532T>C p.S178P | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV62754263; called by muse, mutect2, varscan2
- TEAD2 | c.1176G>C p.Q392H | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60544150; called by muse, mutect2, varscan2
- TJP1 | c.3193A>G p.S1065G | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV62041218; called by muse, mutect2, varscan2
- TLE1 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64686018, COSV64686889; called by muse, mutect2, varscan2
- TMEM138 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); catalogued as COSV53651566; called by muse, mutect2, varscan2
- TNFSF13B | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV65516063; called by muse, mutect2, varscan2
- TNNI2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53289375; called by muse, mutect2, varscan2
- TPR | c.5905G>A p.E1969K | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV66600812; called by muse, varscan2
- TRIM71 | c.2018A>G p.D673G | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV67470673; called by muse, mutect2, varscan2
- TRMT10B | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV53050227; called by muse, mutect2, varscan2
- TRMT9B | c.840C>A p.S280R | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV71600341; called by muse, mutect2
- TTC17 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.267); catalogued as COSV50007807; called by muse, mutect2, varscan2
- TVP23C | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.354); catalogued as COSV56669391, COSV56673088; called by muse, mutect2, varscan2
- UBR4 | c.6153C>A p.F2051L | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV64387334; called by muse, mutect2, varscan2
- UGT1A9 | c.668T>A p.F223Y | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV60836518, COSV60855035; called by muse, mutect2
- UPK3B | c.446C>T p.A149V (on ENST00000257632; = p.A94V on NM_001347684.2) | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.295); catalogued as COSV57536234, COSV57536474; called by muse, mutect2, varscan2
- VEGFC | c.1037C>G p.T346S | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV54596712; called by muse, mutect2, varscan2
- WWC3 | c.1918A>G p.I640V | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs995341102, COSV66502653; called by muse, mutect2, varscan2
- ZC3H8 | c.748A>C p.K250Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55619138; called by muse, mutect2, varscan2
- ZFP37 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65286614; called by muse, mutect2, varscan2
- ZFP82 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV67565107; called by muse, mutect2, varscan2
- ZNF215 | c.1251C>A p.N417K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV53492578; called by muse, mutect2, varscan2
- ZNF22 | c.219C>A p.H73Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53585335; called by muse, mutect2, varscan2
- ZNF397 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 60/157 reads (38%) | catalogued as COSV54350548; called by muse, mutect2, varscan2
- ZNF618 | c.674C>T p.A225V (on ENST00000374126 / NM_001318042.2; = p.A193V on NM_133374.2) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as COSV55919970; called by muse, mutect2, varscan2
- ZNF638 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV52485440; called by muse, mutect2
- ZNF652 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62946722; called by muse, mutect2, varscan2
- ZW10 | c.958A>C p.K320Q | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV52316012; called by muse, mutect2, varscan2
- AP1G2 | c.1447del p.E483Sfs*50 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- C21orf91 | c.621_634del p.E207Dfs*18 | Frame Shift Del (DEL) | VAF 67/242 reads (28%) | called by mutect2, varscan2
- DIAPH1 | c.2316_2336del p.Y773_L779del | In Frame Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- EEF2 | c.2184_2223del p.C728Wfs*23 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel
- ETV5 | c.181+7T>G | Splice Region (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- FAM174C | c.244_246del p.G82del | In Frame Del (DEL) | VAF 42/60 reads (70%) | called by mutect2, pindel, varscan2
- FREM2 | c.2367_2407del p.G790Vfs*28 | Frame Shift Del (DEL) | VAF 38/100 reads (38%) | called by mutect2, pindel
- GABRR1 | c.651_655+4del p.X217_splice | Splice Site (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- ITGA7 | c.2094C>G p.F698L (on ENST00000555728; = p.F654L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- KEAP1 | c.763_766dup p.D256Vfs*95 | Frame Shift Ins (INS) | VAF 20/95 reads (21%) | called by mutect2, pindel, varscan2
- LRP2 | c.10394-12_10394-1del p.X3465_splice | Splice Site (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- MAGI2 | c.965_965+1dup p.X322_splice | Splice Site (INS) | VAF 36/116 reads (31%) | called by pindel, varscan2
- METTL7A | c.591del p.L198Cfs*7 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by pindel, varscan2
- PAIP2 | c.324_329del p.K108_S109del | In Frame Del (DEL) | VAF 41/139 reads (29%) | called by mutect2, pindel, varscan2
- PHLDB2 | c.1599del p.F533Lfs*36 | Frame Shift Del (DEL) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
- PIGV | c.1391_1406del p.C464Yfs*4 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | called by mutect2, pindel, varscan2
- PRKD2 | c.380-25_380del p.X127_splice | Splice Site (DEL) | VAF 24/112 reads (21%) | called by mutect2, pindel
- PTGR1 | c.641_642insAA p.Y214* | Nonsense Mutation (INS) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- RAD9A | c.705T>A p.N235K | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SCAMP4 | c.639_649del p.P214Hfs*148 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- STON1 | c.1974_1980delinsTCTG p.S659_D660delinsL | In Frame Del (DEL) | VAF 59/235 reads (25%) | called by pindel, varscan2*
- TMEM33 | c.211_226delinsG p.H71_H76delinsD | In Frame Del (DEL) | VAF 39/232 reads (17%) | called by pindel, varscan2*
- VPS53 | c.688-8_688del p.X230_splice (on ENST00000571805 / NM_001366253.2; = p.X201_splice on NM_018289.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- ZBTB9 | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ZNF383 | c.1346_1347del p.P449Lfs*2 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- A2M | c.4314A>G p.P1438= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs965842592, COSV59383446; called by muse, mutect2, varscan2
- ACACA | c.981T>C p.Y327= | Silent (SNP) | VAF 47/151 reads (31%) | called by muse, mutect2, varscan2
- ACTL9 | c.1159C>T p.L387= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV61005505; called by muse, mutect2, varscan2
- ALG10B | c.864T>C p.F288= | Silent (SNP) | VAF 122/337 reads (36%) | catalogued as COSV58143001; called by muse, mutect2, varscan2
- AMFR | c.507T>C p.F169= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV51920803; called by muse, mutect2, varscan2
- ANKRD26 | c.1707T>G p.T569= | Silent (SNP) | VAF 70/227 reads (31%) | catalogued as COSV65775015; called by muse, mutect2, varscan2
- CCNA2 | c.958C>T p.L320= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV54665686; called by muse, mutect2, varscan2
- CCNG1 | c.108A>C p.L36= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV61651987; called by muse, mutect2, varscan2
- CELSR2 | c.2571C>T p.G857= | Silent (SNP) | VAF 92/204 reads (45%) | catalogued as rs760728043, COSV54769776, COSV54781703; called by muse, mutect2, varscan2
- CFAP57 | c.39T>C p.G13= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as rs1234166756, COSV52539830; called by muse, mutect2, varscan2
- CHD9 | c.8661A>C p.S2887= (on ENST00000398510 / NM_001382353.1; = p.S2871= on NM_025134.7) | Silent (SNP) | VAF 88/264 reads (33%) | catalogued as COSV54609483; called by muse, mutect2, varscan2
- EID3 | c.363C>T p.D121= | Silent (SNP) | VAF 74/228 reads (32%) | catalogued as COSV61598710; called by muse, mutect2, varscan2
- GBGT1 | c.375C>T p.I125= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV64410070; called by muse, mutect2, varscan2
- GBP3 | c.357C>A p.A119= | Silent (SNP) | VAF 129/274 reads (47%) | catalogued as COSV52518106; called by muse, mutect2, varscan2
- GRIN2A | c.279A>G p.A93= | Silent (SNP) | VAF 30/162 reads (19%) | catalogued as rs763498978, COSV58029061; called by muse, mutect2, varscan2
- HSPA2 | c.900C>T p.I300= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV55969311; called by muse, mutect2, varscan2
- ITGA2 | c.735T>C p.Y245= | Silent (SNP) | VAF 47/154 reads (31%) | catalogued as COSV56858748; called by muse, mutect2, varscan2
- ITIH1 | c.2184G>C p.T728= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV56254166; called by muse, mutect2, varscan2
- ITM2B | c.522T>C p.V174= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV66035076; called by muse, mutect2
- KLB | c.774A>T p.G258= | Silent (SNP) | VAF 59/175 reads (34%) | catalogued as COSV57301208; called by muse, mutect2, varscan2
- LBR | c.75A>G p.V25= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as COSV55288500; called by muse, mutect2, varscan2
- MAP10 | c.612G>A p.L204= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1196636715, COSV69363345; called by muse, mutect2
- METTL7A | c.597T>C p.F199= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV59840655; called by muse, varscan2
- MPP4 | c.558G>A p.G186= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV59630486; called by muse, mutect2, varscan2
- MTMR4 | c.903A>C p.A301= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV60200257; called by muse, mutect2, varscan2
- NF1 | c.525T>C p.H175= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs750358089, COSV62200069; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP11 | c.1521T>G p.L507= | Silent (SNP) | VAF 55/169 reads (33%) | catalogued as COSV64086774; called by muse, mutect2, varscan2
- NOXRED1 | c.453T>C p.N151= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV53627909; called by muse, mutect2, varscan2
- PC | c.2076G>C p.A692= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV58992486; called by muse, mutect2, varscan2
- PDE4A | c.103C>A p.R35= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV61798199; called by muse, mutect2, varscan2
- PECR | c.498A>T p.P166= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV54734065; called by muse, mutect2, varscan2
- PGM3 | c.450A>G p.Q150= | Silent (SNP) | VAF 67/220 reads (30%) | catalogued as rs755097152, COSV52283513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLK2 | c.1128A>G p.K376= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV57106767; called by muse, mutect2, varscan2
- PXDNL | c.2025T>C p.R675= | Silent (SNP) | VAF 65/210 reads (31%) | catalogued as COSV62485547; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RIN3 | c.2883G>T p.R961= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV53656932; called by muse, mutect2, varscan2
- RPL35 | c.159C>T p.S53= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV62018911; called by muse, mutect2, varscan2
- RRS1 | c.117G>A p.L39= | Silent (SNP) | VAF 69/183 reads (38%) | catalogued as COSV52554658; called by muse, mutect2, varscan2
- SCYL3 | c.309G>T p.G103= | Silent (SNP) | VAF 193/363 reads (53%) | catalogued as COSV63045597; called by muse, mutect2, varscan2
- SIM2 | c.1467C>T p.C489= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV51766582; called by muse, mutect2, varscan2
- TAP1 | c.159C>T p.D53= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs770660372, COSV62754272; called by muse, mutect2, varscan2
- THAP2 | c.465C>T p.C155= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as COSV57348382; called by muse, mutect2, varscan2
- UGT1A9 | c.666T>A p.R222= | Silent (SNP) | VAF 114/339 reads (34%) | catalogued as COSV60836510; called by muse, mutect2
- URB2 | c.3714G>A p.G1238= | Silent (SNP) | VAF 117/237 reads (49%) | catalogued as COSV50985159; called by muse, mutect2, varscan2
- VAV3 | c.357T>A p.P119= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV58380916; called by muse, mutect2, varscan2
- ZBTB16 | c.1572C>T p.N524= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV60091855; called by muse, mutect2, varscan2
- ZNF432 | c.540T>A p.S180= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV55416142; called by muse, mutect2, varscan2
- ZNF560 | c.1347A>G p.G449= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV56867271, COSV56871146; called by muse, mutect2, varscan2
- ZNF595 | c.663T>C p.I221= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+11971C>G | Intron (SNP) | VAF 52/154 reads (34%) | catalogued as COSV55336938; called by muse, mutect2, varscan2
- FKRP | c.*532T>G | 3'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100586719; called by muse, mutect2, varscan2
- HMGB1P1 | n.409G>A | RNA (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- IGIP | c.-2005dup | 5'UTR (INS) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- JUN | c.-336T>A | 5'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100973479; called by muse, mutect2, varscan2
- KSR1 | c.1510+516A>C | Intron (SNP) | VAF 39/134 reads (29%) | catalogued as COSV52031108; called by muse, mutect2, varscan2
- LINC02877 | n.333T>C | RNA (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2, varscan2
- MUSK | c.1927+96_1927+104del | Intron (DEL) | VAF 23/225 reads (10%) | called by mutect2, pindel
- RPL23 | c.13+206_13+223del | Intron (DEL) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- TUBE1 | c.152+838T>C | Intron (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- UBAC2 | c.31+570G>A | Intron (SNP) | VAF 149/450 reads (33%) | catalogued as COSV63117720; called by muse, mutect2, varscan2
- UBXN10 | c.*2815T>G | 3'UTR (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- ZNF140 | c.-41A>T | 5'UTR (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- ZNF675 | c.-36A>C | 5'UTR (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100705170; called by muse, mutect2
